Somatic mutation profile of tumor specimen TCGA-GN-A262-06A (aliquot TCGA-GN-A262-06A-11D-A196-08) from TCGA case TCGA-GN-A262, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 55.2 years (20,147 days).
Specimen TCGA-GN-A262-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7121111-d93c-4827-a60d-9a8d610826a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A262-10A (Blood Derived Normal), aliquot TCGA-GN-A262-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efef7c5b-4675-4e32-8d85-739c2573eeb2

The open-access MAF lists 424 somatic variants for this specimen: 274 protein-altering or splice-affecting, 140 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 247, Silent 140, Nonsense Mutation 17, Intron 5, Splice Site 5, RNA 3, Splice Region 3, 5'UTR 1, In Frame Del 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CPA6 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 40/82 reads (49%) | catalogued as rs139145929; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- GRHL2 | c.1258-1G>A p.X420_splice | Splice Site (SNP) | VAF 11/28 reads (39%) | catalogued as rs398123006, CS136797, COSV52549541, COSV99306133; ClinVar: pathogenic; called by muse, mutect2
- AAK1 | c.2731G>T p.D911Y | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV68644358; called by muse, mutect2, varscan2
- ABCA12 | c.5807C>T p.S1936F (on ENST00000272895 / NM_173076.3; = p.S1618F on NM_015657.3) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55962161; called by muse, varscan2
- ADGRF4 | c.983G>A p.R328K | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV51953246, COSV51953694; called by muse, mutect2, varscan2
- ADGRG4 | c.4789C>T p.P1597S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV54958211; called by muse, mutect2, varscan2
- ADGRV1 | c.12829C>T p.R4277* | Nonsense Mutation (SNP) | VAF 11/11 reads (100%) | catalogued as COSV67977934; called by mutect2, varscan2
- AGA | c.341T>A p.V114E | Missense Mutation (SNP) | VAF 137/338 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52806524; called by muse, mutect2, varscan2
- AGAP2 | c.2831C>T p.S944L (on ENST00000547588 / NM_001122772.2; = p.S588L on NM_014770.4) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV57728811, COSV57730525; called by muse, mutect2, varscan2
- AGO2 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV55048306; called by muse, mutect2, varscan2
- AHCTF1 | c.1149T>A p.N383K (on ENST00000366508; = p.N357K on NM_015446.5) | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58251208; called by muse, mutect2, varscan2
- ALG6 | c.1102T>A p.W368R | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54765498; called by muse, mutect2, varscan2
- AMOT | c.1993C>T p.R665W (on ENST00000371959 / NM_001113490.1; = p.R256W on NM_133265.3) | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59064385; called by muse, mutect2, varscan2
- AMOTL2 | c.1752G>A p.M584I | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780371170, COSV51439420; called by muse, mutect2, varscan2
- ANK3 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 43/43 reads (100%) | catalogued as rs1064796340, COSV55061870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO8 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV50175651; called by muse, mutect2, varscan2
- AP5M1 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as rs752677166, COSV55105544; called by muse, mutect2, varscan2
- APLNR | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs866459668, COSV57242954; called by muse, mutect2, varscan2
- ARMC1 | c.362T>A p.F121Y | Missense Mutation (SNP) | VAF 71/130 reads (55%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs900148580, COSV52533872, COSV52533913; called by muse, mutect2, varscan2
- ARMCX2 | c.1288C>T p.L430F | Missense Mutation (SNP) | VAF 76/360 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57530335; called by muse, mutect2, varscan2
- ASNS | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51552798; called by muse, mutect2, varscan2
- ATP13A4 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55070269; called by muse, mutect2, varscan2
- ATP6V0A1 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs545345712, COSV52874096, COSV99231429; called by muse, mutect2, varscan2
- BICDL1 | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 36/86 reads (42%) | catalogued as COSV66908028; called by muse, mutect2, varscan2
- BMERB1 | c.420-1G>A p.X140_splice | Splice Site (SNP) | VAF 25/140 reads (18%) | catalogued as COSV55508915; called by muse, mutect2, varscan2
- C2orf16 | c.5123G>A p.R1708K | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.14); catalogued as rs1418401799, COSV62673693, COSV62675606; called by muse, mutect2, varscan2
- C3 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs775755257, COSV55574338; called by muse, mutect2, varscan2
- C3AR1 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 85/159 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV50819408; called by muse, mutect2, varscan2
- CACNA2D2 | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56564499; called by muse, mutect2, varscan2
- CATSPERD | c.2356G>A p.G786R | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58465648; called by muse, mutect2, varscan2
- CATSPERG | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 143/281 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as rs147603617; called by muse, mutect2, varscan2
- CBLB | c.2153C>T p.S718F | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.054); catalogued as COSV51428712; called by muse, mutect2, varscan2
- CCDC60 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1214394487, COSV59545033; called by muse, mutect2, varscan2
- CCDC81 | c.1289G>A p.R430Q (on ENST00000445632 / NM_001156474.2; = p.R340Q on NM_021827.4) | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143484591; called by muse, mutect2, varscan2
- CCDC88B | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV57266536; called by muse, varscan2
- CCL18 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs768648633; called by muse, mutect2, varscan2
- CCNE1 | c.823T>C p.F275L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV52904705; called by muse, mutect2, varscan2
- CD33 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV51802240; called by muse, mutect2, varscan2
- CEP135 | c.3136C>T p.H1046Y | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV57260671; called by mutect2, varscan2
- CETN2 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV64744211; called by mutect2, varscan2
- CFHR5 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs774353375, COSV56817855; called by mutect2, varscan2
- CHD9 | c.8183G>A p.G2728E (on ENST00000398510 / NM_001382353.1; = p.G2712E on NM_025134.7) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54611475; called by muse, mutect2, varscan2
- CHTF18 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); catalogued as rs766620558, COSV50100874; called by mutect2, varscan2
- CLCN4 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV66465197; called by muse, mutect2, varscan2
- CLEC14A | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.547); catalogued as COSV60562785; called by muse, mutect2, varscan2
- CLRN2 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72512567; called by muse, mutect2, varscan2
- CNTN4 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 26/26 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100639814, COSV61874404; called by muse, mutect2, varscan2
- COL4A6 | c.3205G>T p.G1069* | Nonsense Mutation (SNP) | VAF 100/377 reads (27%) | catalogued as COSV57868546; called by muse, mutect2, varscan2
- COL9A1 | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 92/209 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV57885610; called by muse, mutect2, varscan2
- COMP | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as CM980423, COSV55875094; called by muse, mutect2, varscan2
- CPAMD8 | c.1471C>T p.L491F (on ENST00000651564; = p.L444F on NM_015692.5) | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52235478; called by muse, mutect2, varscan2
- CRYBG2 | c.4579C>T p.R1527C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs199611603, COSV57486597; called by mutect2, varscan2
- CSMD1 | c.6250G>A p.E2084K (on ENST00000520002; = p.E2083K on NM_033225.6) | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV59334123; called by mutect2, varscan2
- CSMD1 | c.3331G>A p.G1111R (on ENST00000520002; = p.G1110R on NM_033225.6) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100153365, COSV59334135; called by muse, mutect2, varscan2
- CTAG2 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.272); catalogued as COSV55994123, COSV55995256; called by muse, mutect2, varscan2
- CYP2C8 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as COSV64877499; called by mutect2, varscan2
- CYP2S1 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59506325; called by muse, mutect2, varscan2
- DCT | c.1348C>A p.Q450K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as COSV65469524; called by mutect2, varscan2
- DDOST | c.256C>T p.L86F (on ENST00000415136; = p.L69F on NM_005216.5) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1183344841, COSV56118959; called by muse, mutect2, varscan2
- DDX18 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.463); catalogued as COSV54307055; called by muse, mutect2, varscan2
- DGKI | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 34/71 reads (48%) | catalogued as rs1259961080, COSV55934682; called by muse, mutect2, varscan2
- DNAH2 | c.1907C>T p.S636F | Missense Mutation (SNP) | VAF 182/341 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV66720683; called by muse, mutect2, varscan2
- DNTTIP1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.107); catalogued as COSV65459923; called by muse, mutect2, varscan2
- DOCK11 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 78/436 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52240511, COSV99353117; called by muse, varscan2
- DSCAM | c.4931G>A p.R1644Q | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.728); catalogued as rs756021849, COSV68020300; called by muse, mutect2, varscan2
- DSCAM | c.4390G>A p.E1464K | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1371989999, COSV68021628; called by muse, mutect2, varscan2
- DSCAM | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.492); catalogued as rs1270212239, COSV68028408; called by muse, mutect2, varscan2
- EEF1A1 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.326); catalogued as COSV58549871; called by muse, mutect2, varscan2
- EHMT2 | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 263/502 reads (52%) | catalogued as rs1160808053; called by muse, mutect2, varscan2
- EMD | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.422); catalogued as COSV100877430, COSV63962243; called by mutect2, varscan2
- ENAM | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV68536131; called by muse, mutect2, varscan2
- ENTPD6 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0.068); catalogued as rs1162730582, COSV61751666; called by muse, mutect2, varscan2
- EPRS1 | c.2347C>T p.Q783* | Nonsense Mutation (SNP) | VAF 42/82 reads (51%) | catalogued as COSV65099465; called by mutect2, varscan2
- ERICH5 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV59315954; called by muse, mutect2, varscan2
- ESM1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV67318634; called by mutect2, varscan2
- EVPL | c.5711C>T p.T1904I | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1214466305, COSV56912165; called by muse, mutect2, varscan2
- F10 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM025195, COSV65022032, COSV65022246; called by muse, mutect2, varscan2
- F8 | c.1805G>A p.R602Q | Missense Mutation (SNP) | VAF 135/587 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs782241116, COSV64274482; called by muse, mutect2, varscan2
- FADS3 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs763222458, COSV53878849; called by muse, mutect2, varscan2
- FAM104B | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV59777225; called by muse, mutect2, varscan2
- FANCM | c.3674G>A p.R1225K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1242913955, COSV57502160; called by muse, mutect2, varscan2
- FAT3 | c.1796C>A p.A599E | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV53121444; called by muse, mutect2, varscan2
- FCER2 | c.105G>A p.W35* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs1398490675, COSV60916596; called by mutect2, varscan2
- FCRL3 | c.674A>G p.Q225R | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.474); catalogued as COSV63842153; called by muse, mutect2, varscan2
- FCRL6 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.61); PolyPhen benign (0.394); catalogued as rs140713881, COSV58941422; called by muse, mutect2, varscan2
- FGD2 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780657307, COSV51464056; called by muse, mutect2, varscan2
- FIG4 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs188910818, COSV57788255; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMNL3 | c.2151C>A p.F717L | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.969); catalogued as COSV53302994; called by mutect2, varscan2
- FRAS1 | c.7973G>A p.G2658E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53617114; called by muse, mutect2, varscan2
- FRMPD2 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1380193103; called by mutect2, varscan2
- GIGYF2 | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs12618284, COSV65250290; called by muse, mutect2, varscan2
- GOLGA7 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 139/307 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.094); catalogued as COSV63299403; called by muse, mutect2, varscan2
- GPAT2 | c.1959G>T p.W653C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64003553; called by mutect2, varscan2
- GPHN | c.1579C>T p.R527C (on ENST00000315266 / NM_001377519.1; = p.R560C on NM_020806.5) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1567363565, COSV59472785; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPRASP1 | c.2107A>G p.I703V | Missense Mutation (SNP) | VAF 279/380 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs757883870, COSV64355796; called by muse, mutect2, varscan2
- GRID1 | c.2594C>T p.P865L | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1437472138; called by muse, mutect2, varscan2
- GRM8 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV58823857, COSV58832398; called by muse, mutect2, varscan2
- GUF1 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55783115; called by muse, mutect2, varscan2
- HAAO | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54311280; called by muse, mutect2, varscan2
- HAUS7 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV57849565; called by muse, mutect2, varscan2
- HGF | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV55950930, COSV55951004; called by muse, mutect2, varscan2
- HIF3A | c.1690C>T p.P564S (on ENST00000377670 / NM_152795.4; = p.P495S on NM_022462.4) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV52199654; called by muse, mutect2, varscan2
- HIVEP3 | c.3646C>T p.P1216S | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs911866004, COSV56016666; called by muse, mutect2, varscan2
- HOXC6 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV54537075; called by muse, mutect2, varscan2
- HSPB7 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs887656677, COSV58892003; called by muse, mutect2, varscan2
- HYDIN | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs267604623, COSV55485377; called by muse, mutect2, varscan2
- IGSF9 | c.1913G>A p.G638E (on ENST00000368094 / NM_001135050.2; = p.G622E on NM_020789.4) | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63638832; called by muse, mutect2, varscan2
- IGSF9B | c.1936C>G p.R646G | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV58068680; called by muse, varscan2
- IL16 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV57264378; called by muse, mutect2, varscan2
- INSIG1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376290152; called by mutect2, varscan2
- IREB2 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51923531; called by muse, mutect2, varscan2
- ITGA8 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 73/129 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV65225664, COSV65237267; called by muse, mutect2, varscan2
- KIAA1586 | c.2116G>T p.E706* | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as COSV66056796; called by muse, mutect2, varscan2
- KIAA1614 | c.2543G>A p.R848K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.558); catalogued as COSV62551025; called by muse, mutect2, varscan2
- KIF17 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV56118968, COSV56122626; called by muse, mutect2, varscan2
- KIF1A | c.4553C>T p.S1518F (on ENST00000320389 / NM_001379639.1; = p.S1510F on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1158291712, COSV57491801; called by muse, varscan2
- KIF1A | c.4508C>T p.S1503F (on ENST00000320389 / NM_001379639.1; = p.S1495F on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV100242257, COSV57491818; called by muse, varscan2
- KIF2B | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV52131459; called by muse, mutect2, varscan2
- KIRREL2 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs780560504, COSV52875760; called by muse, mutect2, varscan2
- KLHL4 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV64143383; called by mutect2, varscan2
- KRT4 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 100/190 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1221027800, COSV53407859; called by muse, mutect2, varscan2
- LAMB4 | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52721221; called by muse, mutect2, varscan2
- LRP1B | c.3646G>A p.D1216N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.996); catalogued as COSV67230462; called by muse, mutect2, varscan2
- LRRC4C | c.945G>A p.W315* | Nonsense Mutation (SNP) | VAF 14/15 reads (93%) | catalogued as rs151083424, COSV53427812; called by muse, mutect2, varscan2
- LTBP2 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.871); catalogued as COSV56209308; called by muse, mutect2, varscan2
- MAG | c.1187A>G p.N396S | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62700987; called by muse, mutect2, varscan2
- MAP1A | c.5576C>A p.P1859Q | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV55809652; called by mutect2, varscan2
- MAPK4 | c.1190C>G p.P397R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); catalogued as rs753551722, COSV68542470; called by muse, mutect2, varscan2
- MECR | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.094); catalogued as COSV55285887; called by muse, mutect2, varscan2
- MGAT3 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.469); catalogued as rs1435551649, COSV57866012; called by muse, mutect2, varscan2
- MPDZ | c.5829G>A p.Q1943= (on ENST00000319217 / NM_001330637.2; = p.Q1914= on NM_003829.5) | Splice Region (SNP) | VAF 10/26 reads (38%) | catalogued as COSV59918955; called by muse, varscan2
- MSR1 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50506780, COSV50514344; called by mutect2, varscan2
- MUC16 | c.40847G>A p.G13616E | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.67); PolyPhen probably damaging (0.997); catalogued as rs200058866, COSV66691823; called by mutect2, varscan2
- MYH13 | c.5768A>G p.K1923R | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV52831244; called by muse, mutect2, varscan2
- NCL | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 123/259 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.573); catalogued as COSV59545515; called by muse, mutect2, varscan2
- NCLN | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 79/182 reads (43%) | catalogued as rs1568315782, COSV55742801; called by muse, mutect2, varscan2
- NFATC2 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.085); catalogued as rs371747422; called by muse, mutect2, varscan2
- NLRP1 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs777635766, COSV52568315; called by mutect2, varscan2
- NLRP9 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV60464080; called by muse, mutect2, varscan2
- NLRP9 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs773656654, COSV60462226; called by mutect2, varscan2
- NMD3 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 69/72 reads (96%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs776286017; called by muse, mutect2, varscan2
- NMD3 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 70/73 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761413485, COSV63618142; called by mutect2, varscan2
- NME8 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs201987014, COSV52246843; called by mutect2, varscan2
- NONO | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV52138119; called by muse, mutect2, varscan2
- NOS1 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV57614165; called by muse, mutect2, varscan2
- NSDHL | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 85/434 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as rs782041671; called by muse, mutect2, varscan2
- OGT | c.2861G>A p.R954Q | Missense Mutation (SNP) | VAF 88/434 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101035579, COSV65481013, COSV65482385; called by muse, varscan2
- OR2T2 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100737736; called by muse, mutect2, varscan2
- OR4A5 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.295); catalogued as rs770249402, COSV60521838; called by muse, mutect2, varscan2
- OR4N5 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV61320752; called by muse, mutect2, varscan2
- OR51M1 | c.727C>A p.Q243K | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV60784722; called by mutect2, varscan2
- OR5D14 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs1366209297, COSV59456723, COSV99045926; called by muse, mutect2, varscan2
- OR6Q1 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 89/186 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56933385; called by muse, mutect2, varscan2
- OSCAR | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.563); catalogued as COSV52927743; called by muse, mutect2, varscan2
- PARP12 | c.761-1G>A p.X254_splice | Splice Site (SNP) | VAF 19/52 reads (37%) | catalogued as COSV54934920; called by muse, mutect2
- PCDH15 | c.1237A>C p.T413P | Missense Mutation (SNP) | VAF 31/32 reads (97%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV57326192; called by muse, mutect2, varscan2
- PCDH9 | c.3511G>A p.D1171N (on ENST00000377865 / NM_203487.3; = p.D1137N on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.135); catalogued as rs369769235; called by muse, mutect2, varscan2
- PCDHB9 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 83/86 reads (97%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.045); catalogued as rs782519267; called by muse, mutect2, varscan2
- PCDHGA11 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs779718690, COSV53963851; called by muse, mutect2, varscan2
- PCDHGB4 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53963841; called by muse, mutect2, varscan2
- PCLO | c.3217C>T p.P1073S | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs766195366, COSV61640008; called by mutect2, varscan2
- PCLO | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.164); catalogued as COSV61640018; called by muse, mutect2, varscan2
- PCLO | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV61640027; called by muse, mutect2, varscan2
- PCM1 | c.2879C>T p.S960L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.395); catalogued as rs1236259577; called by mutect2, varscan2
- PCSK6 | c.311A>G p.E104G | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV60167835; called by muse, mutect2, varscan2
- PHF2 | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs747655204, COSV63681395; called by mutect2, varscan2
- PIK3C2G | c.3836C>T p.S1279L (on ENST00000676171; = p.S1238L on NM_004570.5) | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs935135637, COSV56800636, COSV56812711; called by mutect2, varscan2
- PJVK | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284729307; called by muse, mutect2, varscan2
- PLCB4 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV53804518; called by muse, mutect2, varscan2
- PLCH1 | c.2227C>T p.Q743* (on ENST00000340059 / NM_001130960.2; = p.Q755* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 37/39 reads (95%) | catalogued as COSV58200136; called by muse, mutect2, varscan2
- PLEKHG2 | c.2759C>T p.S920F | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as COSV52679527; called by muse, mutect2, varscan2
- PLEKHH2 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 207/444 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs1223471916, COSV56750155; called by muse, varscan2
- PLIN4 | c.2660G>A p.G887E (on ENST00000301286; = p.G902E on NM_001367868.2) | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs372232842; called by mutect2, varscan2
- PLIN4 | c.2264G>A p.G755E (on ENST00000301286; = p.G770E on NM_001367868.2) | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs753610495; called by muse, mutect2, varscan2
- POU6F1 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV61326602, COSV61326894; called by muse, mutect2, varscan2
- PPP1R9A | c.3149T>G p.M1050R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV56896203; called by muse, mutect2, varscan2
- PPP3CC | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760326256, COSV51499680; called by muse, mutect2, varscan2
- PPP4C | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV54222142; called by muse, mutect2, varscan2
- PRDM11 | c.1048G>A p.A350T (on ENST00000530656 / NM_001359633.1; = p.A316T on NM_001256695.1) | Missense Mutation (SNP) | VAF 92/96 reads (96%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV55440598; called by muse, mutect2, varscan2
- PREX2 | c.2940G>A p.G980= | Splice Region (SNP) | VAF 13/24 reads (54%) | catalogued as COSV55775941, COSV55806314; called by muse, mutect2, varscan2
- PRODH2 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | PolyPhen benign (0); catalogued as COSV56560227; called by muse, mutect2, varscan2
- PROSER1 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.015); catalogued as COSV61487928; called by muse, mutect2, varscan2
- PRRG2 | c.261+1G>A p.X87_splice | Splice Site (SNP) | VAF 36/68 reads (53%) | catalogued as COSV55870449; called by muse, mutect2, varscan2
- PTPRT | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs868189942, COSV61960869; called by mutect2, varscan2
- PXDNL | c.2981G>A p.G994E | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867225480, COSV62485869; called by muse, mutect2, varscan2
- RAI2 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 105/218 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.049); catalogued as COSV58964701; called by muse, mutect2, varscan2
- RELA | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.757); catalogued as rs761250712, COSV58015029; called by muse, mutect2, varscan2
- RXFP2 | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53635130; called by muse, mutect2, varscan2
- RYR2 | c.12409G>A p.E4137K | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267598439, COSV63666259; called by mutect2, varscan2
- SALL3 | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV73306121; called by muse, mutect2, varscan2
- SCN10A | c.1516C>T p.H506Y | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.412); catalogued as COSV71860258; called by muse, mutect2, varscan2
- SERPINB1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs746571131, COSV66313764; called by muse, mutect2, varscan2
- SF3A1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 76/177 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53169423; called by muse, varscan2
- SFTPA1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 109/161 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64867478; called by muse, mutect2, varscan2
- SLC16A10 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 96/204 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64354427; called by muse, mutect2, varscan2
- SLC17A4 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV64956434; called by muse, mutect2, varscan2
- SLC3A1 | c.1835C>T p.S612L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs759732153, COSV53217161; called by mutect2, varscan2
- SLC52A1 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1567734836, COSV54693084; called by muse, mutect2, varscan2
- SLC8B1 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs748038619, COSV52527222; called by mutect2, varscan2
- SLC9C2 | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV62943722; called by muse, mutect2, varscan2
- SLITRK1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 26/26 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs762122393, COSV65676122; called by muse, varscan2
- SPATS2 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs369467557, COSV58918289; called by muse, mutect2, varscan2
- SPEM2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.457); catalogued as COSV100080976, COSV60366957; called by muse, mutect2, varscan2
- ST6GAL2 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 11/18 reads (61%) | PolyPhen benign (0.02); catalogued as rs376167669, COSV64528940, COSV64530316; called by muse, mutect2
- STAT6 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55666511; called by muse, mutect2, varscan2
- SULF1 | c.2207G>A p.G736E | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.424); catalogued as COSV52680995; called by muse, mutect2, varscan2
- SYK | c.1029G>A p.M343I | Missense Mutation (SNP) | VAF 77/80 reads (96%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV65327667; called by muse, mutect2, varscan2
- TAS1R1 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59839994; called by muse, mutect2, varscan2
- TBC1D4 | c.3658T>A p.L1220I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV66490912; called by muse, mutect2, varscan2
- TCEAL3 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 88/371 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as COSV54580710; called by muse, mutect2, varscan2
- TEX101 | c.169G>A p.G57R (on ENST00000598265 / NM_001130011.3; = p.G75R on NM_031451.4) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV53662140; called by muse, mutect2, varscan2
- TINAGL1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV54699233; called by muse, mutect2, varscan2
- TLN2 | c.6133C>A p.L2045M | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60890688; called by muse, mutect2, varscan2
- TLN2 | c.7382G>A p.G2461E | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60890692; called by muse, mutect2, varscan2
- TMCO4 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV53873515; called by muse, mutect2, varscan2
- TMEM52 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1323291728; called by muse, varscan2
- TMPRSS11A | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.523); catalogued as COSV58358988; called by muse, mutect2, varscan2
- TNFRSF6B | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV53927793; called by muse, mutect2, varscan2
- TNRC18 | c.4867C>T p.Q1623* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV68164242; called by muse, mutect2, varscan2
- TOP1 | c.2123G>T p.R708L | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1270229872, COSV63694361, COSV63696019; called by muse, mutect2, varscan2
- TREML2 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.453); catalogued as rs1561889156, COSV72439122; called by muse, mutect2, varscan2
- TRIM60 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.46); catalogued as COSV61970769; called by muse, mutect2, varscan2
- TRMT1 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 32/69 reads (46%) | catalogued as COSV52834881; called by muse, mutect2, varscan2
- TUBGCP6 | c.4717G>A p.D1573N | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV50549741; called by muse, mutect2, varscan2
- TXLNA | c.736C>A p.R246S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65314608; called by muse, mutect2, varscan2
- TYRP1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.722); catalogued as COSV66358034; called by mutect2, varscan2
- UGT2A2 | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54142407; called by muse, mutect2, varscan2
- UGT2B4 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs375014423; called by muse, varscan2
- UGT2B7 | c.229T>C p.Y77H | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV59443756; called by muse, mutect2, varscan2
- USP26 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.264); catalogued as COSV63708483; called by muse, mutect2, varscan2
- UTP14A | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 119/246 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV64087080; called by muse, mutect2, varscan2
- VN1R4 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as rs1486169653, COSV100237484; called by muse, mutect2, varscan2
- WNK3 | c.1317A>T p.K439N | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV63614930; called by muse, mutect2, varscan2
- WSB1 | c.151T>G p.W51G | Missense Mutation (SNP) | VAF 112/230 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52215735; called by muse, mutect2, varscan2
- ZC3HAV1L | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV51964538; called by muse, mutect2, varscan2
- ZC4H2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.066); catalogued as COSV62004111; called by muse, varscan2
- ZC4H2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.096); catalogued as rs1484560905, COSV100564932, COSV62003071; called by muse, varscan2
- ZCCHC12 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 72/381 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV59571518; called by muse, mutect2, varscan2
- ZFPM2 | c.2801C>T p.S934F | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV65874063; called by muse, varscan2
- ZMYM3 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.69); catalogued as COSV58738347; called by muse, mutect2, varscan2
- ZNF211 | c.962C>T p.S321L (on ENST00000347302 / NM_198855.4; = p.S334L on NM_006385.5) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs753395520, COSV53742804; called by muse, varscan2
- ZNF479 | c.1435A>G p.T479A | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.55); PolyPhen benign (0.187); catalogued as COSV58639413; called by muse, mutect2, varscan2
- ZNF48 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.98); PolyPhen benign (0.011); catalogued as COSV60783438; called by muse, mutect2, varscan2
- ZNF578 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs200994015; called by mutect2, varscan2
- ZNF672 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs1407882409, COSV60638111; called by muse, mutect2
- ZNF761 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 76/177 reads (43%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.708); catalogued as COSV61888592; called by muse, mutect2, varscan2
- ZNF768 | c.547A>T p.K183* | Nonsense Mutation (SNP) | VAF 86/126 reads (68%) | catalogued as COSV53223932; called by mutect2, varscan2
- ZNF99 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.015); catalogued as COSV68055536; called by muse, mutect2
- ATRX | c.6205C>T p.L2069F | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.737); called by muse, mutect2
- BMERB1 | c.420G>A p.R140= | Splice Region (SNP) | VAF 25/142 reads (18%) | called by muse, mutect2, varscan2
- C2orf16 | c.5124A>T p.R1708S | Missense Mutation (SNP) | VAF 99/206 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.303); called by mutect2, varscan2
- CDSN | c.1426C>T p.H476Y | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); called by mutect2, varscan2
- COG3 | c.1250T>G p.V417G | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- CORO2A | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DISP3 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.409); called by mutect2, varscan2
- FRG2C | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FZR1 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- GALNT14 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCK | c.1124C>T p.T375I | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MMP19 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 117/258 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MOV10 | c.2575G>A p.D859N | Missense Mutation (SNP) | VAF 92/98 reads (94%) | SIFT deleterious (0.03); PolyPhen benign (0.173); called by muse, varscan2
- PHEX | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNC1 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- POTEA | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PRKACG | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 51/51 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- RXYLT1 | c.1132_1137del p.S378_M379del | In Frame Del (DEL) | VAF 46/93 reads (49%) | called by mutect2, pindel, varscan2
- SMG6 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); called by muse, varscan2
- STRN4 | c.854_855dup p.Q286Cfs*8 | Frame Shift Ins (INS) | VAF 36/87 reads (41%) | called by mutect2, pindel, varscan2
- TBC1D4 | c.3659T>A p.L1220* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- TPTE | c.1277-1G>C p.X426_splice (on ENST00000618007 / NM_199261.4; = p.X408_splice on NM_199259.4) | Splice Site (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- UGGT2 | c.2917C>T p.P973S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by mutect2, varscan2
- WNK3 | c.1316A>T p.K439I | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZMYM3 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM7 | c.504T>C p.Y168= | Silent (SNP) | VAF 63/110 reads (57%) | catalogued as COSV51541135; called by muse, mutect2, varscan2
- ADAMTS15 | c.1422C>T p.A474= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as rs1190756859, COSV54502851, COSV54506331; called by muse, mutect2, varscan2
- ALB | c.24C>T p.S8= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV55738842, COSV55743208; called by muse, mutect2, varscan2
- ALG5 | c.477C>T p.I159= | Silent (SNP) | VAF 53/99 reads (54%) | catalogued as COSV53505792; called by muse, mutect2, varscan2
- ALK | c.2757G>A p.G919= | Silent (SNP) | VAF 40/58 reads (69%) | catalogued as rs1309115542, COSV66571597; called by muse, mutect2, varscan2
- ANKRD28 | c.3072C>T p.S1024= | Silent (SNP) | VAF 80/84 reads (95%) | catalogued as COSV67518455; called by muse, mutect2, varscan2
- ANP32D | c.69C>T p.F23= | Silent (SNP) | VAF 55/145 reads (38%) | catalogued as rs1476485728, COSV56980357; called by muse, mutect2, varscan2
- APOB | c.4722C>T p.T1574= | Silent (SNP) | VAF 221/483 reads (46%) | catalogued as COSV51938661; called by muse, mutect2, varscan2
- ARHGEF16 | c.1335C>T p.S445= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs759612195, COSV65682297; called by muse, mutect2, varscan2
- ARMC5 | c.798C>T p.S266= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV51657149; called by muse, mutect2, varscan2
- ASIC4 | c.1035C>T p.G345= (on ENST00000347842 / NM_182847.3; = p.G364= on NM_018674.6) | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs148110150; called by muse, mutect2, varscan2
- ASPG | c.969C>T p.F323= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs745587624, COSV71933859; called by mutect2, varscan2
- ATP7B | c.3450C>T p.N1150= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as COSV54439510; called by muse, mutect2, varscan2
- ATRX | c.6204C>T p.P2068= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as rs782631268, COSV100970111, COSV64872432; called by muse, mutect2
- B4GALT1 | c.276C>T p.S92= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs762594169, COSV65708192; called by muse, mutect2, varscan2
- BAIAP3 | c.1035C>T p.F345= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as rs774268778, COSV60980281; called by muse, mutect2, varscan2
- BMP10 | c.300C>T p.P100= | Silent (SNP) | VAF 65/134 reads (49%) | catalogued as COSV54895533; called by muse, mutect2, varscan2
- BMP5 | c.1062G>A p.K354= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV63701135; called by muse, mutect2, varscan2
- BSN | c.3003C>T p.S1001= | Silent (SNP) | VAF 23/24 reads (96%) | catalogued as COSV56519894, COSV99610106; called by muse, mutect2, varscan2
- CACNA1E | c.4941G>A p.R1647= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV62399632; called by mutect2, varscan2
- CAMKK1 | c.223C>T p.L75= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs1161429007, COSV50118513, COSV99340294; called by muse, mutect2, varscan2
- CAMSAP3 | c.3462G>A p.K1154= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs756426581, COSV50336950; called by muse, mutect2, varscan2
- CASR | c.2241C>T p.A747= (on ENST00000490131; = p.A824= on NM_000388.4) | Silent (SNP) | VAF 62/66 reads (94%) | catalogued as COSV56138283; called by muse, mutect2, varscan2
- CCDC81 | c.1290G>A p.R430= (on ENST00000445632 / NM_001156474.2; = p.R340= on NM_021827.4) | Silent (SNP) | VAF 50/115 reads (43%) | called by muse, mutect2, varscan2
- CCNA1 | c.357G>A p.K119= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as COSV55222041; called by muse, mutect2, varscan2
- CDSN | c.1425C>T p.P475= | Silent (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- CDSN | c.1257C>T p.S419= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV52538534; called by muse, mutect2, varscan2
- CFAP52 | c.1017C>T p.V339= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV55345511; called by muse, mutect2, varscan2
- CFAP74 | c.2025C>T p.L675= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV54568889; called by muse, mutect2, varscan2
- CNDP1 | c.747C>T p.F249= | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as rs1476412729, COSV62594100; called by mutect2, varscan2
- COG3 | c.1251T>G p.V417= | Silent (SNP) | VAF 73/166 reads (44%) | called by muse, mutect2, varscan2
- CORO2A | c.945C>T p.S315= | Silent (SNP) | VAF 41/47 reads (87%) | catalogued as rs867853923, COSV100673970; called by muse, mutect2, varscan2
- CPEB1 | c.996C>T p.P332= (on ENST00000617958; = p.P272= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs754049552, COSV55619382; called by muse, mutect2, varscan2
- CRB1 | c.2712C>T p.S904= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs1322966199, COSV66331003; called by muse, mutect2, varscan2
- CRTC1 | c.1569G>T p.P523= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV58718135, COSV58720601; called by muse, mutect2, varscan2
- CSF2RA | c.351G>A p.E117= | Silent (SNP) | VAF 151/314 reads (48%) | catalogued as COSV62625012; called by muse, mutect2, varscan2
- CSMD1 | c.1632C>T p.F544= (on ENST00000520002; = p.F543= on NM_033225.6) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100144077, COSV59283795; called by muse, mutect2, varscan2
- CSMD3 | c.240T>C p.G80= | Silent (SNP) | VAF 67/175 reads (38%) | catalogued as rs767598421, COSV52202968; called by muse, mutect2, varscan2
- DCAF12L2 | c.81T>C p.G27= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV63582092, COSV63582934; called by muse, mutect2, varscan2
- DENND2B | c.2241C>T p.F747= | Silent (SNP) | VAF 35/36 reads (97%) | catalogued as COSV58204430; called by muse, mutect2, varscan2
- DISP3 | c.747C>T p.A249= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs1264269688, COSV53829110; called by muse, mutect2, varscan2
- DNAH2 | c.3756C>T p.F1252= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV66720686; called by muse, mutect2, varscan2
- DNAH5 | c.8859C>T p.L2953= | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as COSV54230851; called by muse, mutect2, varscan2
- DUSP2 | c.871C>A p.R291= | Silent (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- EHMT2 | c.471C>T p.A157= | Silent (SNP) | VAF 261/500 reads (52%) | catalogued as rs140758887; called by muse, mutect2, varscan2
- ELOVL1 | c.786C>T p.P262= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV60522250; called by muse, mutect2, varscan2
- EP400 | c.1623G>C p.G541= | Silent (SNP) | VAF 54/112 reads (48%) | catalogued as COSV57774984; called by muse, varscan2
- ESF1 | c.1107C>T p.F369= | Silent (SNP) | VAF 73/152 reads (48%) | catalogued as COSV52521585; called by muse, mutect2, varscan2
- EVX2 | c.1398G>A p.P466= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV57963721; called by muse, mutect2
- FAM120C | c.513C>T p.F171= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV60259761; called by muse, mutect2, varscan2
- FAM47B | c.1860T>G p.S620= | Silent (SNP) | VAF 127/255 reads (50%) | catalogued as COSV61454446; called by muse, mutect2, varscan2
- FBXW7 | c.1632C>G p.V544= (on ENST00000281708 / NM_001349798.2; = p.V464= on NM_018315.5) | Silent (SNP) | VAF 40/42 reads (95%) | catalogued as COSV55923155; called by muse, varscan2
- FCAR | c.345G>A p.L115= | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as COSV62029949; called by muse, mutect2, varscan2
- FER1L6 | c.2928C>T p.T976= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV67550504, COSV67550810; called by muse, mutect2, varscan2
- FRG2C | c.792G>C p.G264= | Silent (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- FUT2 | c.948C>T p.F316= | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as COSV67179426; called by muse, varscan2
- FZR1 | c.648C>T p.T216= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV58052088; called by mutect2, varscan2
- GABBR1 | c.2685C>T p.N895= | Silent (SNP) | VAF 97/204 reads (48%) | catalogued as rs770510256, COSV63542907; called by muse, mutect2, varscan2
- GABRA3 | c.1455C>T p.I485= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV64800011; called by muse, mutect2, varscan2
- GNGT1 | c.177G>A p.E59= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV50352917; called by muse, mutect2, varscan2
- GPR158 | c.102C>T p.S34= | Silent (SNP) | VAF 50/90 reads (56%) | catalogued as rs1321118999, COSV66272313; called by muse, mutect2, varscan2
- GPR20 | c.789C>T p.A263= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as rs776669655; called by muse, mutect2, varscan2
- GRID1 | c.2595C>T p.P865= | Silent (SNP) | VAF 11/11 reads (100%) | called by mutect2, varscan2
- GZMB | c.723G>A p.K241= | Silent (SNP) | VAF 108/205 reads (53%) | catalogued as COSV53541732; called by muse, mutect2, varscan2
- HERC1 | c.11754C>T p.S3918= | Silent (SNP) | VAF 73/150 reads (49%) | catalogued as COSV71248177; called by muse, varscan2
- IFT88 | c.1797T>A p.S599= (on ENST00000319980 / NM_001318493.2; = p.S590= on NM_006531.5 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as rs1390456362, COSV60674086; called by mutect2, varscan2
- IMPDH1 | c.477C>T p.S159= (on ENST00000470772 / NM_001142573.2; = p.S245= on NM_000883.4) | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV58316441; called by muse, varscan2
- INTS5 | c.1638C>T p.L546= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV57952031; called by muse, mutect2, varscan2
- ITPRID1 | c.2115C>A p.S705= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV60075984; called by muse, mutect2, varscan2
- IZUMO1R | c.270C>T p.F90= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as COSV60622877; called by mutect2, varscan2
- KCND2 | c.9G>C p.A3= | Silent (SNP) | VAF 81/182 reads (45%) | catalogued as COSV58583583, COSV58589056; called by muse, mutect2, varscan2
- KCNN1 | c.252G>A p.G84= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV55839400; called by muse, mutect2, varscan2
- KDR | c.1635C>T p.F545= | Silent (SNP) | VAF 77/153 reads (50%) | catalogued as COSV55767075; called by muse, mutect2, varscan2
- KHDRBS3 | c.885C>T p.A295= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV63419672; called by muse, mutect2, varscan2
- KIF1A | c.4755C>T p.S1585= (on ENST00000320389 / NM_001379639.1; = p.S1577= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 64/124 reads (52%) | catalogued as COSV57491773; called by muse, mutect2, varscan2
- KIRREL1 | c.318C>T p.A106= | Silent (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- KIRREL1 | c.319C>T p.L107= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as rs1203309332; called by muse, mutect2, varscan2
- KLRD1 | c.51G>A p.G17= | Silent (SNP) | VAF 53/141 reads (38%) | catalogued as COSV60273851; called by muse, mutect2, varscan2
- KNSTRN | c.103C>T p.L35= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as rs1327576579, COSV51106087; called by muse, mutect2, varscan2
- KRT79 | c.459C>T p.F153= | Silent (SNP) | VAF 96/188 reads (51%) | catalogued as rs376301539, COSV57941207; called by muse, mutect2, varscan2
- LCK | c.1125C>T p.T375= | Silent (SNP) | VAF 47/102 reads (46%) | called by muse, mutect2, varscan2
- LILRB3 | c.411G>A p.G137= | Silent (SNP) | VAF 40/139 reads (29%) | catalogued as rs752502970; called by muse, mutect2, varscan2
- LRCH4 | c.666C>T p.S222= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs760078044, COSV59643499; called by muse, mutect2, varscan2
- MDN1 | c.7329C>T p.L2443= | Silent (SNP) | VAF 65/125 reads (52%) | catalogued as COSV65522984; called by muse, mutect2, varscan2
- MLXIP | c.1287C>T p.L429= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV59835726; called by muse, mutect2, varscan2
- MMP19 | c.1452G>A p.G484= | Silent (SNP) | VAF 118/258 reads (46%) | called by muse, mutect2, varscan2
- MOV10 | c.2574G>A p.K858= | Silent (SNP) | VAF 97/103 reads (94%) | called by muse, varscan2
- MRPL52 | c.126C>T p.P42= | Silent (SNP) | VAF 61/141 reads (43%) | catalogued as COSV61308934; called by muse, mutect2, varscan2
- MSN | c.1218C>G p.A406= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV64304336; called by muse, mutect2, varscan2
- NCAN | c.105G>A p.R35= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV53052492; called by muse, mutect2, varscan2
- NEXMIF | c.3222G>A p.P1074= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as rs748567167, COSV50037885; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP11 | c.846G>A p.G282= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV64087711; called by muse, mutect2, varscan2
- NR2E3 | c.711C>T p.N237= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV58908664; called by muse, mutect2, varscan2
- NSDHL | c.870C>T p.A290= | Silent (SNP) | VAF 83/428 reads (19%) | catalogued as rs1556848473; called by muse, mutect2, varscan2
- OR14J1 | c.201G>A p.L67= | Silent (SNP) | VAF 108/202 reads (53%) | catalogued as COSV65845731; called by muse, varscan2
- OR2T33 | c.855C>T p.P285= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as rs575677824, COSV58815720; called by muse, varscan2
- OR4C16 | c.342C>T p.I114= | Silent (SNP) | VAF 66/135 reads (49%) | catalogued as COSV58942378; called by muse, mutect2, varscan2
- OR4N2 | c.255C>T p.F85= | Silent (SNP) | VAF 85/266 reads (32%) | catalogued as rs139052676, COSV60052198; called by muse, mutect2, varscan2
- OR7E24 | c.585C>T p.F195= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs752023143, COSV71702209, COSV71702240; called by muse, mutect2, varscan2
- PAPPA2 | c.2277G>A p.K759= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as COSV62779640; called by muse, mutect2, varscan2
- PBX1 | c.579C>T p.S193= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV63344595; called by muse, mutect2, varscan2
- PCDHA11 | c.102C>T p.S34= | Silent (SNP) | VAF 58/63 reads (92%) | catalogued as COSV56482014; called by muse, mutect2, varscan2
- PEBP1 | c.435C>T p.H145= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV54337202; called by muse, mutect2, varscan2
- PER1 | c.1974C>T p.T658= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as rs1235282072, COSV57920058; called by muse, mutect2, varscan2
- PHEX | c.1500C>T p.A500= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs1440858200; called by mutect2, varscan2
- PHF8 | c.369C>T p.F123= (on ENST00000357988 / NM_001184896.1; = p.F87= on NM_015107.3) | Silent (SNP) | VAF 84/369 reads (23%) | catalogued as rs782085570, COSV57681894; called by muse, mutect2, varscan2
- PJVK | c.51G>A p.G17= | Silent (SNP) | VAF 47/91 reads (52%) | called by muse, mutect2, varscan2
- PKDREJ | c.2199C>T p.L733= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as COSV53549845; called by muse, mutect2, varscan2
- PLCH1 | c.2082C>T p.N694= (on ENST00000340059 / NM_001130960.2; = p.N706= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/37 reads (100%) | catalogued as COSV58200167; called by muse, mutect2, varscan2
- PLG | c.354A>G p.T118= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV51983750; called by muse, mutect2, varscan2
- PLIN4 | c.2265G>A p.G755= (on ENST00000301286; = p.G770= on NM_001367868.2) | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as rs763841484; called by muse, mutect2, varscan2
- PLXNC1 | c.2247C>T p.S749= | Silent (SNP) | VAF 79/180 reads (44%) | called by muse, mutect2, varscan2
- PRKACG | c.999G>A p.E333= | Silent (SNP) | VAF 50/50 reads (100%) | catalogued as rs760618026; called by muse, mutect2, varscan2
- PTPN5 | c.288C>T p.F96= | Silent (SNP) | VAF 37/38 reads (97%) | catalogued as COSV62126507; called by muse, mutect2, varscan2
- PXDNL | c.930C>T p.S310= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs533757469, COSV62478192; called by muse, mutect2, varscan2
- RERE | c.1579C>T p.L527= | Silent (SNP) | VAF 59/113 reads (52%) | catalogued as COSV61943486; called by muse, mutect2, varscan2
- RIMBP2 | c.684C>T p.F228= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as rs766901586, COSV55473128; called by mutect2, varscan2
- RNF216 | c.2500C>T p.L834= (on ENST00000425013 / NM_207116.3; = p.L891= on NM_207111.4) | Silent (SNP) | VAF 60/118 reads (51%) | catalogued as COSV101111373, COSV66290875; called by muse, varscan2
- SACS | c.9183C>T p.L3061= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV101207184, COSV66541152; called by muse, mutect2, varscan2
- SLC15A1 | c.693C>T p.N231= | Silent (SNP) | VAF 49/129 reads (38%) | catalogued as COSV64712284; called by mutect2, varscan2
- SLC44A5 | c.834G>A p.V278= | Silent (SNP) | VAF 14/14 reads (100%) | catalogued as rs566016844, COSV63766835; called by mutect2, varscan2
- SLC4A4 | c.768C>T p.S256= (on ENST00000264485 / NM_001098484.3; = p.S212= on NM_003759.4) | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV52626407; called by muse, mutect2, varscan2
- SLC6A14 | c.96G>A p.E32= | Silent (SNP) | VAF 86/363 reads (24%) | catalogued as COSV64147349; called by muse, mutect2, varscan2
- SLC9A3 | c.1524C>T p.S508= | Silent (SNP) | VAF 48/48 reads (100%) | catalogued as COSV53801901; called by muse, mutect2, varscan2
- SMG6 | c.720C>T p.S240= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as rs765211008, COSV53976316; called by muse, varscan2
- SORCS3 | c.3006C>T p.S1002= | Silent (SNP) | VAF 17/19 reads (89%) | catalogued as COSV63795597; called by muse, varscan2
- SPTBN5 | c.8289G>A p.E2763= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV58022358; called by muse, mutect2, varscan2
- SRC | c.1533C>T p.T511= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs774888105, COSV62440093; called by muse, mutect2, varscan2
- STAU1 | c.1578G>A p.Q526= (on ENST00000371856 / NM_001319135.1; = p.Q445= on NM_004602.3) | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV61459713; called by muse, mutect2, varscan2
- SYNE1 | c.294C>T p.F98= | Silent (SNP) | VAF 50/92 reads (54%) | catalogued as COSV55003798; called by muse, mutect2, varscan2
- TENT5B | c.1239C>T p.L413= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as rs1247777435, COSV56693171; called by muse, mutect2, varscan2
- TLCD3A | c.351C>T p.N117= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as rs1183545212, COSV56746173; called by muse, mutect2, varscan2
- TREML1 | c.468G>A p.Q156= | Silent (SNP) | VAF 50/116 reads (43%) | catalogued as rs1295658958, COSV64191289; called by muse, mutect2, varscan2
- TRIM15 | c.843C>T p.F281= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as COSV64989740; called by muse, mutect2, varscan2
- TTN | c.8844G>A p.S2948= (on ENST00000591111; = p.S2902= on NM_003319.4) | Silent (SNP) | VAF 54/130 reads (42%) | catalogued as rs531976829, COSV60114547; ClinVar: likely benign; called by muse, varscan2
- UMODL1 | c.2487C>T p.S829= (on ENST00000408910 / NM_001004416.2; = p.S957= on NM_173568.3) | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV68570079; called by muse, mutect2, varscan2
- ZMYM3 | c.516C>T p.S172= | Silent (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- ZNF142 | c.4212C>T p.F1404= (on ENST00000411696 / NM_001379660.1; = p.F1204= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV68744055; called by muse, mutect2, varscan2
- ZNF777 | c.1665C>T p.F555= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs549811811, COSV56098178; called by muse, mutect2, varscan2
- ZNF792 | c.579C>T p.G193= | Silent (SNP) | VAF 164/330 reads (50%) | catalogued as COSV68693526; called by muse, varscan2
- AL353804.6 | chrX:73833244 C>T | 5'Flank (SNP) | VAF 43/149 reads (29%) | catalogued as rs1329021775; called by muse, mutect2, varscan2
- HERC2P3 | n.1562G>A | RNA (SNP) | VAF 17/92 reads (18%) | called by mutect2, varscan2
- MIR1323 | n.17C>T | RNA (SNP) | VAF 78/130 reads (60%) | called by muse, mutect2, varscan2
- MIR200B | n.44G>A | RNA (SNP) | VAF 15/32 reads (47%) | catalogued as rs771703952; called by muse, mutect2, varscan2
- NBL1 | c.-4G>A | 5'UTR (SNP) | VAF 18/43 reads (42%) | catalogued as rs539038673, COSV57030229; called by muse, mutect2, varscan2
- NFASC | c.2470+2049A>G | Intron (SNP) | VAF 33/71 reads (46%) | catalogued as COSV58367452; called by muse, mutect2, varscan2
- SPTB | c.6345+2906C>T | Intron (SNP) | VAF 98/259 reads (38%) | catalogued as COSV100731167; called by muse, mutect2, varscan2
- TRAPPC6A | c.84+25G>A | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- TTN | c.10361-4903G>A | Intron (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100593962; called by muse, mutect2, varscan2
- TTN | c.10361-5158C>T | Intron (SNP) | VAF 7/14 reads (50%) | catalogued as COSV59903094; called by muse, mutect2, varscan2
